Somatic mutation profile of tumor specimen HTMCP-03-06-02334-01A (aliquot HTMCP-03-06-02334-01A-01D-9392) from CGCI case HTMCP-03-06-02334, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamotransitional cell carcinoma; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G2; Age at diagnosis: 40.2 years (14,696 days).
Specimen HTMCP-03-06-02334-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e173d36d-d853-460a-a640-abe32a1d2a5f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02334-10A (Blood Derived Normal), aliquot HTMCP-03-06-02334-10A-01D-9392; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3352bdd-0a6a-4711-b869-9b68fd9f964a

The open-access MAF lists 70 somatic variants for this specimen: 47 protein-altering or splice-affecting, 12 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 12, Nonsense Mutation 6, Intron 5, RNA 3, 3'UTR 2, Splice Site 2, Frame Shift Ins 1, 5'UTR 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 45/105 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AMY2A | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as rs763130583, COSV70214339, COSV70214969, COSV70215021; called by muse, mutect2, varscan2
- CABLES1 | c.1741G>A p.E581K (on ENST00000256925 / NM_001100619.2; = p.E316K on NM_138375.2) | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.906); catalogued as rs768447551, COSV56935557; called by muse, mutect2, varscan2
- CYP11B2 | c.1150C>T p.R384* | Nonsense Mutation (SNP) | VAF 20/57 reads (35%) | catalogued as rs752975169, CM128632, COSV59998259; called by muse, mutect2, varscan2
- FN1 | c.7075C>G p.Q2359E (on ENST00000359671 / NM_001365524.2; = p.Q2328E on NM_002026.4) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.974); catalogued as rs995762610; called by muse, mutect2, varscan2
- GEMIN4 | c.2867C>T p.A956V | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs369029997; called by muse, mutect2, varscan2
- HYDIN | c.10130G>A p.R3377H | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369423572; called by muse, mutect2, varscan2
- MYOCD | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 133/308 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV58504990; called by muse, mutect2, varscan2
- P3H2 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.292); catalogued as rs758731716; called by muse, mutect2, varscan2
- PCED1B | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs759303227; called by muse, mutect2, varscan2
- PCNX3 | c.967C>G p.L323V | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.952); catalogued as COSV100482358; called by muse, mutect2, varscan2
- PDE4DIP | c.4387G>A p.E1463K | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.212); catalogued as COSV57696920; called by muse, mutect2, varscan2
- PLXND1 | c.5646G>C p.K1882N | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.999); catalogued as COSV100139410, COSV100140044; called by muse, mutect2, varscan2
- PPP4R4 | c.1351G>T p.D451Y | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV58553755, COSV58554813; called by muse, mutect2, varscan2
- RBM33 | c.2372G>A p.R791H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs759755140; called by muse, mutect2, varscan2
- SETD1B | c.3134C>T p.S1045L | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious, low confidence (0); catalogued as rs370992202; called by muse, varscan2
- SIPA1L1 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 131/324 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.805); catalogued as rs753416693; called by muse, mutect2, varscan2
- SNTB1 | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.509); catalogued as COSV67328979, COSV67329759; called by muse, mutect2, varscan2
- STXBP5L | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs367712321; called by muse, mutect2, varscan2
- TEX14 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs140312980, COSV53619127; called by muse, mutect2, varscan2
- TOPORS | c.2972C>T p.S991L | Missense Mutation (SNP) | VAF 88/193 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); catalogued as COSV62116884; called by muse, mutect2, varscan2
- TXNDC16 | c.1381G>T p.V461F | Missense Mutation (SNP) | VAF 81/215 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs746462458; called by muse, mutect2, varscan2
- USP49 | c.1250C>G p.S417C | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); catalogued as rs1168030286; called by muse, mutect2, varscan2
- ADAMTS7 | c.3101C>G p.S1034* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | called by muse, varscan2
- CACNA2D1 | c.2345-1G>C p.X782_splice (on ENST00000356253 / NM_001366867.1; = p.X770_splice on NM_000722.4) | Splice Site (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2
- CACNB1 | c.1729G>A p.G577R | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH2 | c.8700G>A p.R2900= | Splice Region (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- DNAH2 | c.8853G>C p.Q2951H | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- F5 | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 33/81 reads (41%) | called by muse, mutect2, varscan2
- FAT1 | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 65/164 reads (40%) | called by muse, mutect2, varscan2
- FHDC1 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- FLNA | c.1357_1374del p.V453_V458del | In Frame Del (DEL) | VAF 8/21 reads (38%) | called by mutect2, pindel, varscan2
- HRNR | c.6935C>G p.S2312C | Missense Mutation (SNP) | VAF 94/1219 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2
- IMPG2 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 70/329 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by mutect2, varscan2
- LAMA4 | c.1228G>A p.E410K (on ENST00000230538 / NM_001105206.3; = p.E403K on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- LIMA1 | c.1231C>T p.H411Y | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MROH2A | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- PKD1 | c.2684C>T p.S895L | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- PLEKHG1 | c.2677C>A p.L893M | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PORCN | c.946+2_946+3del p.X316_splice (on ENST00000326194 / NM_203475.3; = p.X305_splice on NM_022825.4 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 46/148 reads (31%) | called by pindel, varscan2
- PRKG2 | c.2050C>T p.R684W | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- RUNX1T1 | c.886C>A p.P296T (on ENST00000265814 / NM_001198628.1; = p.P269T on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); called by muse, varscan2
- SORCS3 | c.2076C>A p.F692L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- SPEN | c.5533G>T p.E1845* | Nonsense Mutation (SNP) | VAF 52/116 reads (45%) | called by muse, mutect2, varscan2
- SPEN | c.7310_7311insT p.A2438Sfs*5 | Frame Shift Ins (INS) | VAF 30/106 reads (28%) | called by mutect2, pindel*, varscan2
- TTC6 | c.1255C>T p.L419F (on ENST00000267368; = p.L1785F on NM_001310135.3) | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF517 | c.84G>C p.W28C | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- ABCA1 | c.5256C>T p.L1752= | Silent (SNP) | VAF 34/84 reads (40%) | called by muse, mutect2, varscan2
- ARHGEF15 | c.1269C>T p.F423= | Silent (SNP) | VAF 45/111 reads (41%) | catalogued as COSV62725565; called by muse, mutect2, varscan2
- ASTN1 | c.75C>T p.G25= | Silent (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- CIC | c.831C>T p.G277= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs891408662; called by muse, mutect2, varscan2
- ITPR2 | c.5820G>A p.L1940= | Silent (SNP) | VAF 27/49 reads (55%) | called by muse, mutect2, varscan2
- KDM2A | c.2985C>A p.L995= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV100445879; called by muse, mutect2, varscan2
- NPHP3 | c.1581C>T p.L527= | Silent (SNP) | VAF 46/161 reads (29%) | catalogued as rs183241346; called by muse, mutect2, varscan2
- NUP210 | c.384C>T p.L128= | Silent (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2, varscan2
- PLXND1 | c.3675G>A p.Q1225= | Silent (SNP) | VAF 28/149 reads (19%) | called by muse, mutect2, varscan2
- SBNO2 | c.816G>A p.A272= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs960813641; called by muse, mutect2, varscan2
- SMYD2 | c.498C>T p.F166= | Silent (SNP) | VAF 54/124 reads (44%) | catalogued as rs775244264, COSV65290630; called by muse, mutect2, varscan2
- ZAN | c.5505G>A p.P1835= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs755450631, COSV100770515; called by muse, mutect2, varscan2
- AC145350.3 | n.5C>T | RNA (SNP) | VAF 33/88 reads (38%) | catalogued as rs560914723; called by muse, varscan2
- ADGRG6 | c.*42A>G | 3'UTR (SNP) | VAF 52/118 reads (44%) | called by muse, mutect2, varscan2
- AKNA | c.275-24G>C | Intron (SNP) | VAF 14/43 reads (33%) | catalogued as COSV56312641; called by muse, mutect2, varscan2
- CCDC57 | c.2241+6173C>A | Intron (SNP) | VAF 90/206 reads (44%) | called by muse, mutect2, varscan2
- COL9A1 | c.781-110G>A | Intron (SNP) | VAF 18/36 reads (50%) | catalogued as COSV100295549; called by muse, mutect2, varscan2
- DUXAP10 | n.3495C>A | RNA (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- IGSF1 | c.667+50C>T | Intron (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- LRRC55 | c.*3T>C | 3'UTR (SNP) | VAF 17/63 reads (27%) | catalogued as rs963328179; called by muse, mutect2, varscan2
- MUC19 | n.12134G>C | RNA (SNP) | VAF 234/623 reads (38%) | called by muse, mutect2, varscan2
- PHC3 | c.537+43G>C | Intron (SNP) | VAF 24/66 reads (36%) | called by muse, mutect2, varscan2
- TUBGCP5 | c.-17C>T | 5'UTR (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
